TCGA case TCGA-A7-A4SD — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8c09f413-e938-4f2e-a414-84f0e7fcfe41

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 52.4 years (19,131 days); Year of diagnosis: 2012; Method of diagnosis: Core Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 6; Micrometastasis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Docetaxel; Days to treatment start: 64 days; Days to treatment end: 134 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 168 days; Disease response: Tumor Free.
- Days to follow up: 441 days (1.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (FISH): 1.3; Cell count: 20; Specialized molecular test: Signal ratio.
- ERBB2 (FISH): Copy Number Reported; Copy number: 6.4; Cell count: 20.
- ERBB2 (IHC): Equivocal; Staining intensity value: 2+.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Negative.
- PGR (IHC): Negative.
- Test (FISH): Copy Number Reported; Copy number: 5; Cell count: 20.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A7-A4SD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 230 mg.
  Slide TCGA-A7-A4SD-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 10; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A7-A4SD-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A7-A4SD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-A7-A4SD-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 980 mg.
  Slide TCGA-A7-A4SD-11A-03-TS3: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 80; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide TCGA-A7-A4SD-11A-04-TS4: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 85; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A7-A4SD-11A-02-TS2: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 95; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A7-A4SD-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 75; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Her2 cent17 ratio: 1.3; Axillary staging method: Sentinel node biopsy alone; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: Yes; Her2 IHC score: 2+; Method initial path diagnosis: Core needle biopsy; Her2 fish method: PathVysion HER-2 DNA Probe Kit; Prospective collection: Yes; Retrospective collection: No; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 2: Pharmaceutical therapy drug name: Cytoxan.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 441 days; disease-specific survival: no event (censored), 441 days; disease-free interval: no event (censored), 441 days; progression-free interval: no event (censored), 441 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A7-A4SD-01A-11D-A25N-01): tumor purity 0.48, ploidy 2.67, whole-genome doublings 1.
